Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A1QL, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A1QL-01A (Primary Tumor).

[page 1 of 2]
Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type: OUTPATIENT
Additional Copy to:

Ref. Source:

ICB-0-3 Carcinoma, follicular variant 8340/3
Site: Thyroid, NOS C73.9 W 3/10/11

Clinical Diagnosis & History:

Bilateral thyroid nodule dominant left nodule FNA-follicular lesion.

Specimens Submitted:

1: SP:Thyroid, total thyroidectomy

DIAGNOSIS:

1. SP:Thyroid, total thyroidectomy:

Tumor Type:

Papillary carcinoma, follicular variant

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Other Tumor Features:

Calcification of non-psammoma type

Tumor Location:

Left lobe

Tumor Size:

Greatest diameter is 2.2 cm.
On measured slide

Tumor Encapsulation:

Completely surrounded

Capsular Invasion:

Not identified

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Not identified

Surgical Margins:

Free of tumor

Tumor Multicentricity:

Not identified

[page 2 of 2]
Non-Neoplastic Thyroid:
Exhibits nodular hyperplasia
Parathyroid Glands:
Not identified

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1.) The specimen is received fresh, labeled "total thyroidectomy" and consists of a thyroid weighing 26 g. The right lobe measures 3.5 x 2.5 x 1.5 cm, the left lobe measures 4 x 3 x 2.5 cm and the isthmus measures by 2 x 0.5 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals a well-circumscribed tan-yellow to tan-pink mass with a thin capsule measuring 2.1 x 1.8 x 1.8 cm in the left lobe. Sections through the remaining tissue reveal tan-red beefy parenchyma. The remaining thyroid parenchyma is red tan and beefy. Representative sections of the specimen are submitted for TPS. The remaining tissue is serially sectioned and entirely submitted.

Summary of sections:

N - nodule
RL - right lobe
LL - left lobe
IS - isthmus

Summary of Sections:

Part 1: SP:Thyroid, total thyroidectomy

Block	Sect. Site	PCs
4	IS	4
2	LL	2
3	N	3
5	RL	5

Source: NCI Genomic Data Commons file 731bf26a-8546-494f-a6e7-baf2cc00dd07 (TCGA-DJ-A1QL.67D84E08-AE0D-458A-B886-94C22D856A52.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).